Somatic mutation profile of tumor specimen ALCH-ABF8-TTP1-A (aliquot ALCH-ABF8-TTP1-A-1-0-D-A486-36) from ALCHEMIST case ALCH-ABF8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,260 days).
Specimen ALCH-ABF8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f53d64c-e46f-45d2-9408-557606dfddc7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABF8-NB1-A (Blood Derived Normal), aliquot ALCH-ABF8-NB1-A-1-0-D-A486-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da3afb6b-63e3-47ce-9cd2-72ad37b2b025

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 9 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Intron 3, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2A | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV101034591; called by muse, mutect2
- ATP8B1 | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 32/335 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs776511349; called by muse, mutect2
- CELF5 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 62/393 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs148579507; called by muse, mutect2, varscan2
- DTL | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 66/546 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs146481751; called by muse, mutect2, varscan2
- FAM71B | c.727G>A p.G243R | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs768102015, COSV57228119; called by muse, mutect2
- GOLGA3 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.851); catalogued as rs554041677, COSV52628679; called by muse, mutect2
- INSR | c.239A>G p.K80R | Missense Mutation (SNP) | VAF 78/740 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs775877781; called by muse, mutect2, varscan2
- KMT2A | c.5257A>G p.M1753V | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.914); catalogued as rs1555043361, COSV100628874; called by muse, mutect2
- LYRM7 | c.34A>G p.K12E | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as rs1157286475; called by muse, mutect2
- NHSL1 | c.1925A>G p.N642S | Missense Mutation (SNP) | VAF 78/647 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.386); catalogued as rs1247367067; called by muse, mutect2, varscan2
- TAZ | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 24/285 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); catalogued as rs794729166, COSV50010331; ClinVar: uncertain significance; called by muse, mutect2
- VPS13B | c.9034C>A p.P3012T | Missense Mutation (SNP) | VAF 74/718 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62152503; called by muse, mutect2, varscan2
- WWC2 | c.1057_1059del p.E353del | In Frame Del (DEL) | VAF 96/680 reads (14%) | catalogued as rs761420166; called by pindel, varscan2
- ZNF711 | c.1984C>G p.L662V | Missense Mutation (SNP) | VAF 25/605 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as COSV99341285; called by muse, mutect2
- ADAMTS20 | c.1175A>T p.E392V | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATP6V0D1 | c.95_101del p.D32Afs*9 | Frame Shift Del (DEL) | VAF 36/220 reads (16%) | called by mutect2, pindel, varscan2
- KCNH1 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- KCNH8 | c.1476T>A p.D492E | Missense Mutation (SNP) | VAF 65/494 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- LOX | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- MAP3K10 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 17/470 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2
- MAP4K3 | c.232G>T p.G78* | Nonsense Mutation (SNP) | VAF 7/159 reads (4%) | called by muse, mutect2
- PDGFD | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 23/731 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- PDZD4 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- PLK4 | c.2728C>A p.Q910K | Missense Mutation (SNP) | VAF 23/348 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.931); called by muse, mutect2
- PRMT9 | c.778G>C p.G260R | Missense Mutation (SNP) | VAF 60/605 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RPL8 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 28/262 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- RPP40 | c.958A>T p.S320C | Missense Mutation (SNP) | VAF 21/572 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SENP1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC17A8 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 21/615 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); called by muse, mutect2
- SLC28A3 | c.1319C>T p.A440V | Missense Mutation (SNP) | VAF 69/262 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TC2N | c.989C>T p.T330I | Missense Mutation (SNP) | VAF 75/514 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- CARD11 | c.597C>T p.D199= | Silent (SNP) | VAF 20/578 reads (3%) | catalogued as COSV62718034; called by muse, mutect2
- DGKG | c.1896C>G p.L632= | Silent (SNP) | VAF 63/555 reads (11%) | called by muse, mutect2, varscan2
- DGKG | c.234C>T p.A78= | Silent (SNP) | VAF 34/208 reads (16%) | catalogued as COSV99404297; called by muse, mutect2, varscan2
- EHD1 | c.447C>T p.I149= | Silent (SNP) | VAF 14/286 reads (5%) | called by muse, mutect2
- GABRE | c.1131C>G p.L377= | Silent (SNP) | VAF 46/422 reads (11%) | called by muse, mutect2, varscan2
- PGM2 | c.378C>T p.T126= | Silent (SNP) | VAF 36/588 reads (6%) | catalogued as rs757734777; called by muse, mutect2
- RPL8 | c.273C>T p.G91= | Silent (SNP) | VAF 26/253 reads (10%) | called by muse, mutect2, varscan2
- SLITRK1 | c.636C>T p.N212= | Silent (SNP) | VAF 22/568 reads (4%) | catalogued as COSV65676740; called by muse, mutect2
- ZNF716 | c.489C>T p.V163= | Silent (SNP) | VAF 36/426 reads (8%) | called by muse, mutect2
- C5orf63 | c.171+794A>C | Intron (SNP) | VAF 7/184 reads (4%) | called by muse, mutect2
- SLC22A4 | c.394-14G>A | Intron (SNP) | VAF 23/486 reads (5%) | called by muse, mutect2
- ZNF492 | c.-27G>A | 5'UTR (SNP) | VAF 64/441 reads (15%) | catalogued as rs752117369, COSV101513950; called by muse, mutect2, varscan2
- ZNF720 | c.3+975C>T | Intron (SNP) | VAF 55/427 reads (13%) | called by muse, mutect2, varscan2
